Somatic mutation profile of tumor specimen C3L-00599-01 (aliquot CPT0081260007) from CPTAC case C3L-00599, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: male; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G1; Age at diagnosis: 62.4 years (22,781 days).
Specimen C3L-00599-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 44feabf4-77a1-44c0-9dab-413192e63a63.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-00599-31 (Blood Derived Normal), aliquot CPT0081300002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7c020cc7-04f9-4aaa-b7ca-2bc2a7ccdce8

The open-access MAF lists 41 somatic variants for this specimen: 25 protein-altering or splice-affecting, 8 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 22, Silent 8, Intron 5, Frame Shift Del 2, 5'UTR 2, Splice Region 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ERBB2 | c.929C>A p.S310Y | Missense Mutation (SNP) | VAF 23/266 reads (9%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1057519816, COSV54062198, COSV54062802; ClinVar: likely pathogenic; called by muse, mutect2
- ACTN2 | c.655G>A p.A219T | Missense Mutation (SNP) | VAF 25/397 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs1246542277, COSV63978630; ClinVar: uncertain significance; called by muse, mutect2
- ALAS2 | c.1715G>A p.R572H | Missense Mutation (SNP) | VAF 14/118 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as CM114507; called by muse, mutect2, varscan2
- HK3 | c.808G>A p.V270I | Missense Mutation (SNP) | VAF 20/205 reads (10%) | SIFT tolerated (0.97); PolyPhen benign (0.023); catalogued as rs150272942; called by muse, mutect2, varscan2
- NUP210L | c.3029C>T p.S1010F | Missense Mutation (SNP) | VAF 14/222 reads (6%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.545); catalogued as COSV55157757; called by muse, mutect2
- RNF222 | c.331G>A p.A111T | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs1329313606; called by muse, mutect2, varscan2
- SEMA5B | c.2426C>T p.P809L | Missense Mutation (SNP) | VAF 12/174 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.981); catalogued as COSV52094717; called by muse, mutect2
- TBC1D9 | c.3550G>A p.G1184R | Missense Mutation (SNP) | VAF 14/204 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.455); catalogued as rs778747040; called by muse, mutect2
- TMEM100 | c.164G>A p.R55H | Missense Mutation (SNP) | VAF 23/254 reads (9%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); catalogued as rs746630975, COSV70118095, COSV70118125; called by muse, mutect2
- ZNF415 | c.1580G>T p.S527I | Missense Mutation (SNP) | VAF 40/252 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV54702581; called by muse, mutect2, varscan2
- AGAP3 | c.586G>A p.V196M (on ENST00000622464; = p.V232M on NM_031946.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- APPBP2 | c.469C>A p.L157I | Missense Mutation (SNP) | VAF 16/158 reads (10%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.745); called by muse, mutect2
- BCL2L14 | c.812A>C p.K271T | Missense Mutation (SNP) | VAF 42/400 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- COMMD9 | c.295A>G p.T99A | Missense Mutation (SNP) | VAF 20/278 reads (7%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.642); called by muse, mutect2
- CROCC2 | c.2973G>T p.E991D | Missense Mutation (SNP) | VAF 12/100 reads (12%) | SIFT tolerated (0.36); PolyPhen benign (0.061); called by muse, mutect2
- GLI3 | c.124+5G>C | Splice Region (SNP) | VAF 38/416 reads (9%) | called by muse, mutect2
- PCDH17 | c.1900C>A p.H634N | Missense Mutation (SNP) | VAF 40/245 reads (16%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.739); called by muse, mutect2, varscan2
- PLAA | c.2315_2318del p.I772Kfs*12 | Frame Shift Del (DEL) | VAF 22/114 reads (19%) | called by mutect2, pindel, varscan2
- PPCS | c.520_525delinsC p.M174Lfs*15 | Frame Shift Del (DEL) | VAF 28/165 reads (17%) | called by pindel, varscan2*
- RYR2 | c.11053G>A p.D3685N | Missense Mutation (SNP) | VAF 18/278 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- SETX | c.2167C>A p.P723T | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT tolerated (0.16); PolyPhen benign (0); called by muse, mutect2
- ST6GAL2 | c.544A>G p.R182G | Missense Mutation (SNP) | VAF 30/198 reads (15%) | PolyPhen benign (0.001); called by muse, mutect2, varscan2
- STX8 | c.466G>A p.D156N | Missense Mutation (SNP) | VAF 19/176 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- TFIP11 | c.1198T>C p.C400R | Missense Mutation (SNP) | VAF 5/61 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- ZBED9 | c.2363G>T p.S788I | Missense Mutation (SNP) | VAF 33/263 reads (13%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- ASB17 | c.810C>T p.T270= | Silent (SNP) | VAF 12/178 reads (7%) | catalogued as COSV52409194; called by muse, mutect2
- CCDC166 | c.237C>T p.Y79= | Silent (SNP) | VAF 12/249 reads (5%) | catalogued as rs1554616961, COSV101545814; called by muse, mutect2
- DAND5 | c.138G>T p.G46= | Silent (SNP) | VAF 7/49 reads (14%) | called by muse, mutect2, varscan2
- EMX1 | c.351C>T p.L117= | Silent (SNP) | VAF 9/121 reads (7%) | called by muse, mutect2
- EMX2 | c.681G>T p.G227= | Silent (SNP) | VAF 49/469 reads (10%) | catalogued as COSV101463626; called by muse, mutect2, varscan2
- ERBB2 | c.930C>T p.S310= | Silent (SNP) | VAF 23/268 reads (9%) | catalogued as rs974531857, COSV54068756; called by muse, mutect2
- SPIN2A | c.621T>C p.D207= | Silent (SNP) | VAF 17/102 reads (17%) | called by mutect2, varscan2
- TACR3 | c.780G>A p.L260= | Silent (SNP) | VAF 23/322 reads (7%) | catalogued as rs768209062; ClinVar: likely benign; called by muse, mutect2
- DPYS | c.1444-17G>A | Intron (SNP) | VAF 22/371 reads (6%) | catalogued as rs774996693; called by muse, mutect2
- GSDMD | c.580-22C>T | Intron (SNP) | VAF 17/203 reads (8%) | catalogued as rs780783370, COSV52796670; called by muse, mutect2
- MIR1185-1 | n.69T>C | RNA (SNP) | VAF 28/148 reads (19%) | called by muse, mutect2, varscan2
- NLGN4Y | c.-332C>G | 5'UTR (SNP) | VAF 46/230 reads (20%) | called by muse, mutect2, varscan2
- TMEM258 | c.3+23C>T | Intron (SNP) | VAF 27/271 reads (10%) | called by muse, mutect2, varscan2
- TNC | c.4579+4151G>T | Intron (SNP) | VAF 19/130 reads (15%) | called by muse, varscan2
- TPO | c.2748+185C>T | Intron (SNP) | VAF 12/79 reads (15%) | called by muse, mutect2
- ZNF716 | c.-9C>T | 5'UTR (SNP) | VAF 12/267 reads (4%) | catalogued as rs782340963, COSV70780074; called by muse, mutect2
